Somatic mutation profile of tumor specimen C3L-10231-03 (aliquot CPT0527560016) from CPTAC case C3L-10231, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 79.9 years (29,177 days).
Specimen C3L-10231-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 783dee08-890e-4a4f-92c3-3a60a4d98dbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-10231-31 (Blood Derived Normal), aliquot CPT0527630002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0700b36c-0927-45e4-9f45-54b4441954d5

The open-access MAF lists 224 somatic variants for this specimen: 168 protein-altering or splice-affecting, 50 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 50, Nonsense Mutation 12, Frame Shift Del 3, Frame Shift Ins 2, Intron 2, 5'Flank 1, 5'UTR 1, 3'UTR 1, Nonstop Mutation 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 139/637 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.3532C>T p.R1178* | Nonsense Mutation (SNP) | VAF 25/399 reads (6%) | catalogued as rs748140587, COSV52197962; called by muse, mutect2
- ACSM1 | c.470C>G p.S157C | Missense Mutation (SNP) | VAF 57/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1431401736; called by muse, mutect2, varscan2
- ADAD2 | c.1448G>A p.R483H (on ENST00000315906 / NM_001145400.2; = p.R565H on NM_139174.4) | Missense Mutation (SNP) | VAF 239/1037 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377666664; called by muse, mutect2, varscan2
- ADAMTS14 | c.2867G>A p.R956Q | Missense Mutation (SNP) | VAF 241/1165 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as rs778750921, COSV64601596; called by muse, mutect2, varscan2
- ADAMTS20 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 125/533 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1270702920, COSV67129732; called by muse, mutect2, varscan2
- ANKFN1 | c.2957G>A p.G986D (on ENST00000653862; = p.G839D on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/642 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73719184; called by muse, mutect2, varscan2
- ANO3 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 32/496 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs760680753, COSV56807795, COSV99882662; called by muse, mutect2
- APOB | c.5690G>A p.R1897H | Missense Mutation (SNP) | VAF 84/673 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs199510126, CM141896, COSV51922311, COSV51953906; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ASCL4 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 114/1066 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766771512; called by muse, varscan2
- ATG2A | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 106/928 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs746013952, COSV65965826; called by muse, mutect2, varscan2
- AXIN1 | c.1393G>T p.E465* | Nonsense Mutation (SNP) | VAF 308/1132 reads (27%) | catalogued as COSV51984197; called by muse, mutect2, varscan2
- BSN | c.9916C>T p.R3306W | Missense Mutation (SNP) | VAF 83/786 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs770494525; called by muse, mutect2, varscan2
- CAMTA2 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 74/470 reads (16%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.835); catalogued as rs1173602698, COSV100772300; called by muse, mutect2, varscan2
- CCDC6 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 45/522 reads (9%) | catalogued as rs746439006, COSV99569346; called by muse, mutect2
- CD1D | c.481T>G p.L161V | Missense Mutation (SNP) | VAF 167/722 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1173138241, COSV63808527, COSV63808964; called by muse, mutect2, varscan2
- CD8A | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 168/875 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs751865065; called by muse, mutect2, varscan2
- CDH9 | c.487T>G p.L163V | Missense Mutation (SNP) | VAF 90/437 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50253829, COSV99145286, COSV99163241; called by muse, mutect2, varscan2
- CNGA3 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 246/1150 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs546831778, COSV55624691; called by muse, mutect2, varscan2
- CYP4F11 | c.971C>T p.T324I | Missense Mutation (SNP) | VAF 124/585 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56127158; called by muse, mutect2, varscan2
- DNMT1 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 167/703 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs1064796687, COSV61578151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPF2 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 65/577 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52890488; called by muse, mutect2, varscan2
- EPDR1 | c.69G>T p.W23C | Missense Mutation (SNP) | VAF 344/1385 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV52262451; called by muse, mutect2, varscan2
- FAM117B | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 161/808 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.805); catalogued as rs369591557; called by muse, mutect2, varscan2
- FAM151A | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 244/1000 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.102); catalogued as rs779194676; called by muse, mutect2, varscan2
- FAM81B | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 101/527 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as COSV51982079; called by muse, mutect2, varscan2
- FGR | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 112/823 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as rs1362437486; called by muse, mutect2, varscan2
- FREM1 | c.5704C>A p.Q1902K | Missense Mutation (SNP) | VAF 151/729 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs1383436744; called by muse, mutect2, varscan2
- GLI3 | c.3566G>A p.R1189H | Missense Mutation (SNP) | VAF 294/1195 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV67885386, COSV67889835; called by muse, mutect2, varscan2
- GREM2 | c.500A>C p.K167T | Missense Mutation (SNP) | VAF 103/400 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as COSV58954235; called by muse, mutect2, varscan2
- GRIA1 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 123/571 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.029); catalogued as rs371725726; called by muse, mutect2, varscan2
- GRM5 | c.2867C>T p.T956M (on ENST00000305447 / NM_001143831.2; = p.T924M on NM_000842.4) | Missense Mutation (SNP) | VAF 108/1007 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.482); catalogued as rs1193446284, COSV59591456; called by muse, mutect2, varscan2
- GRM8 | c.1049T>G p.L350R | Missense Mutation (SNP) | VAF 112/591 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.076); catalogued as rs748110836; called by muse, mutect2, varscan2
- GRM8 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 62/1008 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147289844, COSV100282975; called by muse, mutect2
- GSDMA | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 195/919 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs375928728; called by muse, mutect2, varscan2
- HDLBP | c.2344G>A p.A782T | Missense Mutation (SNP) | VAF 147/827 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.477); catalogued as rs1200458864, COSV100190315; called by muse, mutect2, varscan2
- HSP90AB1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 63/682 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs775484859; called by muse, mutect2
- ICAM5 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 102/722 reads (14%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.986); catalogued as rs749165436; called by muse, mutect2, varscan2
- IFITM1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 122/1013 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as rs774010868; called by muse, mutect2, varscan2
- IGFL3 | c.208G>C p.G70R | Missense Mutation (SNP) | VAF 60/1024 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58242768; called by muse, mutect2
- KCNK2 | c.1015G>A p.E339K (on ENST00000444842 / NM_001017425.3; = p.E324K on NM_014217.4) | Missense Mutation (SNP) | VAF 173/794 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV101221984; called by muse, mutect2, varscan2
- KDM6A | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 78/183 reads (43%) | catalogued as COSV65045212; called by muse, mutect2, varscan2
- KIF18A | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 152/579 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.534); catalogued as rs776978896; called by muse, mutect2, varscan2
- KSR1 | c.688G>A p.V230M (on ENST00000644974 / NM_001367810.1; = p.V93M on NM_014238.2) | Missense Mutation (SNP) | VAF 273/1255 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as rs569738697, COSV52035562, COSV52039057; called by muse, mutect2, varscan2
- L3MBTL1 | c.2326G>A p.D776N (on ENST00000418998 / NM_001377303.1; = p.D686N on NM_015478.7) | Missense Mutation (SNP) | VAF 170/768 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs773063331; called by muse, mutect2, varscan2
- LEMD3 | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57652332; called by muse, mutect2
- LTF | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 179/686 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as rs563611764, COSV51607809; called by muse, mutect2, varscan2
- MARCHF11 | c.97A>C p.T33P | Missense Mutation (SNP) | VAF 68/406 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1253922432, COSV100198137; called by mutect2, varscan2
- MN1 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 152/1135 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.038); catalogued as COSV56559505; called by muse, mutect2, varscan2
- MROH5 | c.2581G>A p.G861S | Missense Mutation (SNP) | VAF 201/1176 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs748313427, COSV71303024; called by muse, mutect2, varscan2
- MUC16 | c.29114T>G p.L9705R | Missense Mutation (SNP) | VAF 165/764 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.529); catalogued as rs952835263; called by muse, mutect2, varscan2
- MUC16 | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 172/786 reads (22%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs367716629; called by muse, mutect2, varscan2
- MYOCD | c.684dup p.S229Qfs*17 | Frame Shift Ins (INS) | VAF 124/600 reads (21%) | catalogued as rs760792013; called by mutect2, varscan2
- NAPSA | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 139/1154 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as rs368271566; called by muse, mutect2, varscan2
- NAV3 | c.5336G>A p.G1779D | Missense Mutation (SNP) | VAF 30/650 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs561651492, COSV57117288; called by muse, mutect2
- NBN | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 62/383 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55371043; called by muse, mutect2, varscan2
- NCAM2 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 63/657 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs772941307; called by muse, mutect2, varscan2
- NEFM | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 189/1036 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1295045498; called by muse, mutect2, varscan2
- NLGN1 | c.1631C>A p.T544K | Missense Mutation (SNP) | VAF 103/517 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64342867; called by muse, mutect2, varscan2
- NPAS3 | c.2393C>T p.A798V (on ENST00000356141 / NM_001164749.2; = p.A766V on NM_022123.3) | Missense Mutation (SNP) | VAF 78/940 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1414798530, COSV60825331; called by muse, mutect2
- NRDE2 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 87/809 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs766273350; called by muse, mutect2, varscan2
- NTRK3 | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 88/793 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs770581794, COSV58124249; called by muse, mutect2, varscan2
- NUP58 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 108/701 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.341); catalogued as rs373048208; called by muse, mutect2, varscan2
- OR2G3 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 75/747 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs754136402; called by muse, mutect2, varscan2
- OR2T3 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 137/1097 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100613388, COSV62082035; called by muse, mutect2, varscan2
- OR7C2 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 57/465 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.919); catalogued as rs758780405; called by muse, mutect2, varscan2
- PCDHB10 | c.649G>T p.G217C | Missense Mutation (SNP) | VAF 103/1035 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53375757; called by muse, mutect2, varscan2
- PCDHB4 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 153/913 reads (17%) | catalogued as rs544068787, COSV52020208; called by muse, mutect2, varscan2
- PCDHB4 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 303/1779 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as rs149487286, COSV52021296; called by muse, mutect2, varscan2
- PKN3 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 196/926 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs200438464, COSV99404082; called by muse, mutect2, varscan2
- POTEE | c.2673G>T p.K891N | Missense Mutation (SNP) | VAF 118/2702 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.92); catalogued as COSV58228050; called by muse, mutect2
- PROKR2 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 213/834 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.885); catalogued as rs199696443, COSV54085354; called by muse, mutect2, varscan2
- RNF17 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 38/916 reads (4%) | catalogued as COSV55036205; called by muse, mutect2
- SDC2 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 72/917 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772069532, COSV56227922; called by muse, mutect2
- SIX2 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 122/1294 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57389844; called by muse, mutect2
- SMO | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 139/968 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs878919378, COSV50852045; called by muse, mutect2, varscan2
- STYXL2 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 69/676 reads (10%) | catalogued as rs377245710; called by muse, mutect2, varscan2
- SYNE1 | c.14416G>A p.E4806K (on ENST00000367255 / NM_182961.4; = p.E4735K on NM_033071.3) | Missense Mutation (SNP) | VAF 38/694 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs746657854; ClinVar: uncertain significance; called by muse, mutect2
- SYNGR4 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 213/952 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs953051001, COSV61225614; called by muse, mutect2, varscan2
- TDRD9 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 75/646 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs1467738407, COSV59143229; called by muse, mutect2, varscan2
- TLN1 | c.3665G>C p.R1222P | Missense Mutation (SNP) | VAF 72/556 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV59212265; called by muse, mutect2, varscan2
- TRAM2 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 56/424 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754282909, COSV99480410; called by muse, mutect2, varscan2
- TRIM43 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 168/901 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.227); catalogued as rs370094486; called by muse, mutect2, varscan2
- TSSK1B | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 91/1027 reads (9%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs374467859; called by muse, mutect2
- TTN | c.19105C>T p.R6369* (on ENST00000591111; = p.R5442* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 103/916 reads (11%) | catalogued as rs750071765, COSV60086827; called by muse, mutect2, varscan2
- USP6NL | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 91/884 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53212107; called by muse, mutect2, varscan2
- UTF1 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 121/1105 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV58678870; called by muse, mutect2, varscan2
- VSTM2A | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 294/1085 reads (27%) | catalogued as COSV56494101; called by muse, mutect2, varscan2
- ZC3H3 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 336/1137 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs755582447; called by muse, mutect2, varscan2
- ZNF43 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 132/593 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs773949501; called by muse, mutect2, varscan2
- ZNF521 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 40/932 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV64122832; called by muse, mutect2
- ZNF536 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 225/1010 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs746480413, COSV62818075; called by muse, mutect2, varscan2
- ZNF569 | c.1999T>C p.C667R | Missense Mutation (SNP) | VAF 163/795 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779338055, COSV57593432; called by muse, mutect2, varscan2
- ADCY1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 104/661 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AQP3 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 33/1453 reads (2%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.722); called by muse, mutect2
- ATG9B | c.2261G>A p.G754E | Missense Mutation (SNP) | VAF 66/966 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.156); called by muse, mutect2
- BHLHE22 | c.368C>A p.A123D | Missense Mutation (SNP) | VAF 251/1418 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); called by muse, varscan2
- CAMTA1 | c.3469G>A p.V1157M | Missense Mutation (SNP) | VAF 98/928 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); called by muse, mutect2
- CATSPERZ | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 126/613 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC105 | c.898G>C p.A300P | Missense Mutation (SNP) | VAF 103/519 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- CCDC168 | c.5897T>G p.L1966W | Missense Mutation (SNP) | VAF 94/1008 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.465); called by muse, mutect2
- CD207 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 148/736 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CD72 | c.311G>A p.C104Y | Missense Mutation (SNP) | VAF 178/965 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CD80 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 110/580 reads (19%) | called by muse, mutect2, varscan2
- CDIN1 | c.158_165del p.K53Tfs*11 | Frame Shift Del (DEL) | VAF 51/321 reads (16%) | called by mutect2, pindel, varscan2
- CDKL1 | c.353G>A p.C118Y | Missense Mutation (SNP) | VAF 21/578 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDKN2A | c.233_234del p.L78Hfs*41 | Frame Shift Del (DEL) | VAF 244/1610 reads (15%) | called by pindel, varscan2
- CEP85L | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 79/666 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- CHMP3 | c.474G>T p.E158D | Missense Mutation (SNP) | VAF 30/574 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.328); called by muse, mutect2
- CHRM3 | c.805C>A p.Q269K | Missense Mutation (SNP) | VAF 126/580 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- CRISPLD1 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 184/805 reads (23%) | called by muse, mutect2, varscan2
- DST | c.7058G>A p.G2353E | Missense Mutation (SNP) | VAF 58/534 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2
- EFEMP1 | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 129/615 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EPB41L4B | c.1427del p.P476Qfs*49 | Frame Shift Del (DEL) | VAF 127/822 reads (15%) | called by mutect2, pindel, varscan2
- FOXP2 | c.65C>A p.T22N | Missense Mutation (SNP) | VAF 66/906 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2
- FSHR | c.117G>C p.E39D | Missense Mutation (SNP) | VAF 59/830 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.069); called by muse, mutect2
- GRIA2 | c.1871G>A p.G624D | Missense Mutation (SNP) | VAF 94/452 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC2 | c.12370G>A p.G4124R | Missense Mutation (SNP) | VAF 120/1087 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMCN1 | c.2660T>C p.L887P | Missense Mutation (SNP) | VAF 92/352 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- HS6ST2 | c.747C>A p.N249K | Missense Mutation (SNP) | VAF 99/734 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGLV2-18 | c.287T>C p.I96T | Missense Mutation (SNP) | VAF 48/923 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- IGSF1 | c.3778G>T p.G1260W | Missense Mutation (SNP) | VAF 17/601 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ITGAX | c.2174A>G p.D725G | Missense Mutation (SNP) | VAF 58/502 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KAT2A | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 112/930 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- KAZN | c.950C>A p.P317H | Missense Mutation (SNP) | VAF 71/723 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KCNH1 | c.1100A>C p.K367T (on ENST00000271751 / NM_172362.3; = p.K340T on NM_002238.4) | Missense Mutation (SNP) | VAF 174/841 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KRT15 | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 88/823 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC16 | c.33754A>C p.T11252P | Missense Mutation (SNP) | VAF 74/700 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- MYH7 | c.5568_5570del p.E1856del | In Frame Del (DEL) | VAF 72/479 reads (15%) | called by pindel, varscan2
- NCAPD3 | c.2609G>C p.R870T | Missense Mutation (SNP) | VAF 145/778 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- NDN | c.303G>C p.K101N | Missense Mutation (SNP) | VAF 89/894 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NEB | c.4279G>T p.V1427F | Missense Mutation (SNP) | VAF 55/379 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- NUP210L | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 68/375 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- P2RX2 | c.1106C>A p.T369N | Missense Mutation (SNP) | VAF 221/971 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PHC1 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 118/647 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PIK3R6 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 97/883 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PMEL | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 183/764 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PPP2R3A | c.555A>C p.K185N | Missense Mutation (SNP) | VAF 61/576 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PREX1 | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 150/657 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRUNE2 | c.2072C>G p.P691R | Missense Mutation (SNP) | VAF 146/678 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PYROXD1 | c.1503A>C p.*501Yext*71 | Nonstop Mutation (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- RTN4R | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 251/920 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.9986dup p.A3330Gfs*7 | Frame Shift Ins (INS) | VAF 115/662 reads (17%) | called by mutect2, pindel, varscan2
- SAMD1 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 105/178 reads (59%) | PolyPhen benign (0.338); called by muse, mutect2, varscan2
- SCN1A | c.5981T>C p.V1994A (on ENST00000303395 / NM_001202435.3; = p.V1983A on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/838 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2
- SCN2A | c.2927A>G p.N976S | Missense Mutation (SNP) | VAF 119/590 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCN9A | c.3924G>T p.R1308S (on ENST00000303354; = p.R1297S on NM_002977.3) | Missense Mutation (SNP) | VAF 66/340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SLC8A3 | c.338C>T p.T113I | Missense Mutation (SNP) | VAF 46/573 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- SMG6 | c.2784G>T p.Q928H | Missense Mutation (SNP) | VAF 133/616 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TACC2 | c.5492C>G p.P1831R | Missense Mutation (SNP) | VAF 122/639 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TCERG1L | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 152/1091 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM132D | c.1581G>T p.Q527H | Missense Mutation (SNP) | VAF 121/1218 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2
- TMEM200A | c.1378C>T p.L460F | Missense Mutation (SNP) | VAF 55/504 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMTC3 | c.2698G>A p.A900T | Missense Mutation (SNP) | VAF 42/422 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- TNFAIP8 | c.524T>C p.F175S | Missense Mutation (SNP) | VAF 105/517 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TPM2 | c.663T>G p.Y221* | Nonsense Mutation (SNP) | VAF 77/924 reads (8%) | called by muse, mutect2
- TRDMT1 | c.569A>T p.E190V | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- TRHDE | c.2444G>A p.R815K | Missense Mutation (SNP) | VAF 41/623 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.552); called by muse, mutect2
- TRPM3 | c.990A>C p.Q330H (on ENST00000357533 / NM_001366142.2; = p.Q175H on NM_020952.6) | Missense Mutation (SNP) | VAF 120/478 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- VSTM2A | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 84/648 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ZBTB24 | c.59G>C p.S20T | Missense Mutation (SNP) | VAF 63/605 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ZC3HAV1 | c.483T>G p.I161M | Missense Mutation (SNP) | VAF 56/865 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- ZNF254 | c.427A>C p.N143H | Missense Mutation (SNP) | VAF 47/346 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ZNF43 | c.374A>C p.K125T | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZNF696 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 174/2090 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF789 | c.884G>A p.S295N | Missense Mutation (SNP) | VAF 109/818 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF835 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 135/1063 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- ZNF879 | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 114/634 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ADAMTS20 | c.1770C>T p.N590= | Silent (SNP) | VAF 62/551 reads (11%) | catalogued as rs763702051, COSV67127794; called by muse, mutect2, varscan2
- ATP2A2 | c.1902C>T p.I634= | Silent (SNP) | VAF 100/1058 reads (9%) | called by muse, mutect2
- BCL11B | c.2127G>A p.S709= (on ENST00000357195 / NM_001282237.2; = p.S638= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 239/1083 reads (22%) | catalogued as rs375263416; called by muse, mutect2, varscan2
- BNC2 | c.2202C>T p.G734= | Silent (SNP) | VAF 98/881 reads (11%) | catalogued as rs376030025; ClinVar: not provided; called by muse, mutect2, varscan2
- C10orf71 | c.3799C>T p.L1267= | Silent (SNP) | VAF 299/1223 reads (24%) | called by muse, mutect2, varscan2
- COL4A3 | c.1221C>T p.G407= | Silent (SNP) | VAF 240/1326 reads (18%) | called by muse, mutect2
- CSMD2 | c.1161C>T p.S387= | Silent (SNP) | VAF 127/591 reads (21%) | catalogued as rs1460366579, COSV53963621; called by muse, mutect2, varscan2
- CTAGE9 | c.1137G>A p.K379= | Silent (SNP) | VAF 18/502 reads (4%) | called by muse, mutect2
- CUX2 | c.1623C>T p.G541= | Silent (SNP) | VAF 357/1393 reads (26%) | catalogued as rs750439909, COSV55624883; called by muse, mutect2, varscan2
- CYP3A4 | c.1035C>T p.P345= | Silent (SNP) | VAF 99/467 reads (21%) | called by muse, mutect2, varscan2
- DSC1 | c.1887C>T p.A629= | Silent (SNP) | VAF 48/227 reads (21%) | catalogued as rs144470856; called by muse, mutect2, varscan2
- ENO4 | c.1809G>A p.A603= (on ENST00000622726; = p.A600= on NM_001242699.2) | Silent (SNP) | VAF 178/891 reads (20%) | catalogued as rs746639233; called by muse, mutect2, varscan2
- FGB | c.334T>C p.L112= | Silent (SNP) | VAF 121/513 reads (24%) | called by muse, mutect2, varscan2
- FYN | c.1560G>A p.L520= | Silent (SNP) | VAF 72/658 reads (11%) | called by muse, mutect2, varscan2
- G6PC | c.1071G>A p.L357= | Silent (SNP) | VAF 54/459 reads (12%) | catalogued as COSV53830073; called by muse, mutect2, varscan2
- GRIN2C | c.1551C>T p.S517= | Silent (SNP) | VAF 186/887 reads (21%) | catalogued as rs201943001, COSV53115780, COSV99501041; called by muse, mutect2, varscan2
- HHIPL1 | c.1926G>A p.A642= | Silent (SNP) | VAF 66/415 reads (16%) | called by muse, mutect2, varscan2
- HRH3 | c.1083C>T p.A361= | Silent (SNP) | VAF 252/1159 reads (22%) | catalogued as rs772081169; called by muse, mutect2, varscan2
- HTR1A | c.66C>A p.G22= | Silent (SNP) | VAF 232/982 reads (24%) | catalogued as COSV60501130, COSV60501259; called by muse, mutect2, varscan2
- IFNA2 | c.495T>C p.V165= | Silent (SNP) | VAF 30/258 reads (12%) | catalogued as rs759783215; called by muse, mutect2, varscan2
- ING1 | c.1101C>T p.I367= | Silent (SNP) | VAF 98/1156 reads (8%) | catalogued as rs372476660, COSV58167275, COSV58169429; called by muse, mutect2
- IRGQ | c.1383G>A p.A461= | Silent (SNP) | VAF 151/1141 reads (13%) | catalogued as rs745423880; called by muse, varscan2
- KAT6A | c.5943C>T p.P1981= | Silent (SNP) | VAF 101/830 reads (12%) | catalogued as rs1297927467; called by muse, mutect2, varscan2
- LAP3 | c.21G>T p.P7= | Silent (SNP) | VAF 117/618 reads (19%) | called by muse, mutect2, varscan2
- MAGEE1 | c.1746C>A p.G582= | Silent (SNP) | VAF 125/678 reads (18%) | catalogued as COSV63911564; called by muse, mutect2, varscan2
- MUC12 | c.3450T>G p.P1150= (on ENST00000379442; = p.P1007= on NM_001164462.1) | Silent (SNP) | VAF 162/964 reads (17%) | called by muse, mutect2, varscan2
- MVD | c.1158C>T p.C386= | Silent (SNP) | VAF 116/790 reads (15%) | catalogued as rs774639483, COSV55367803; called by muse, mutect2, varscan2
- NAA80 | c.852A>G p.K284= (on ENST00000417393 / NM_001200018.2; = p.K306= on NM_012191.4) | Silent (SNP) | VAF 21/783 reads (3%) | called by muse, mutect2
- NEFM | c.465C>T p.R155= | Silent (SNP) | VAF 165/1338 reads (12%) | catalogued as COSV55333689; called by muse, mutect2, varscan2
- NKX1-1 | c.654C>T p.G218= | Silent (SNP) | VAF 230/1090 reads (21%) | called by muse, mutect2, varscan2
- OR2T6 | c.402C>A p.V134= | Silent (SNP) | VAF 166/1489 reads (11%) | called by muse, mutect2, varscan2
- OR4S1 | c.921G>A p.G307= | Silent (SNP) | VAF 111/524 reads (21%) | catalogued as rs557081664; called by muse, mutect2, varscan2
- OR8J1 | c.897G>A p.K299= | Silent (SNP) | VAF 123/653 reads (19%) | catalogued as COSV57319562; called by muse, mutect2, varscan2
- PAH | c.336T>C p.D112= | Silent (SNP) | VAF 53/589 reads (9%) | catalogued as COSV100187655; called by muse, mutect2
- PDZD2 | c.2763C>T p.L921= | Silent (SNP) | VAF 135/682 reads (20%) | catalogued as rs757662594; called by muse, mutect2, varscan2
- PSCA | c.103C>T p.L35= | Silent (SNP) | VAF 158/872 reads (18%) | called by muse, mutect2, varscan2
- PTCD2 | c.852T>C p.N284= | Silent (SNP) | VAF 38/437 reads (9%) | called by muse, mutect2
- RAI14 | c.204C>T p.C68= | Silent (SNP) | VAF 126/653 reads (19%) | called by muse, mutect2, varscan2
- RNF182 | c.345G>A p.L115= | Silent (SNP) | VAF 121/793 reads (15%) | called by muse, mutect2, varscan2
- SATB1 | c.1662G>A p.R554= | Silent (SNP) | VAF 128/586 reads (22%) | called by muse, mutect2, varscan2
- SELP | c.981G>A p.L327= | Silent (SNP) | VAF 90/507 reads (18%) | called by muse, mutect2, varscan2
- SFTPC | c.348C>T p.A116= | Silent (SNP) | VAF 92/724 reads (13%) | catalogued as COSV59346370; called by muse, varscan2
- SP140 | c.2181G>A p.P727= | Silent (SNP) | VAF 44/375 reads (12%) | catalogued as rs781364258; called by muse, mutect2, varscan2
- SSTR3 | c.600G>A p.A200= | Silent (SNP) | VAF 253/1019 reads (25%) | catalogued as rs777795056; called by muse, mutect2, varscan2
- SYCE2 | c.316C>T p.L106= | Silent (SNP) | VAF 83/464 reads (18%) | called by muse, mutect2, varscan2
- TCERG1L | c.1323G>A p.T441= | Silent (SNP) | VAF 114/1148 reads (10%) | catalogued as rs748229777, COSV64049051; called by muse, mutect2
- TMEM271 | c.837G>A p.A279= | Silent (SNP) | VAF 42/169 reads (25%) | called by muse, mutect2, varscan2
- TRIM64B | c.297G>A p.K99= | Silent (SNP) | VAF 84/1472 reads (6%) | called by muse, mutect2
- VAX2 | c.63C>T p.G21= | Silent (SNP) | VAF 166/1634 reads (10%) | catalogued as rs1553409579; called by muse, mutect2
- ZNF721 | c.1899G>A p.E633= (on ENST00000338977; = p.E645= on NM_133474.4) | Silent (SNP) | VAF 173/722 reads (24%) | catalogued as COSV59089882; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916318 G>A | 5'Flank (SNP) | VAF 110/1431 reads (8%) | catalogued as COSV58118135; called by muse, mutect2
- ARHGEF4 | c.-366G>A | 5'UTR (SNP) | VAF 104/573 reads (18%) | catalogued as rs943638580; called by muse, mutect2, varscan2
- LUC7L2 | c.*1030T>C | 3'UTR (SNP) | VAF 115/679 reads (17%) | catalogued as rs914596485; called by muse, mutect2, varscan2
- NEDD4L | c.297+3674G>A | Intron (SNP) | VAF 108/609 reads (18%) | catalogued as rs1199140242; called by muse, mutect2, varscan2
- NPAP1L | n.161A>G | RNA (SNP) | VAF 88/378 reads (23%) | catalogued as COSV101638905; called by muse, mutect2, varscan2
- PENK | c.138+123C>T | Intron (SNP) | VAF 66/1102 reads (6%) | called by muse, mutect2
